Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-7046, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-7046-01A (Primary Tumor).

[page 1 of 3]
Other Related Data:

Billing Type:
Financial Number:

Clinical Diagnosis & History:

Left renal mass.

Specimens Submitted:

- 1: SP: Left upper pole, left kidney tumor
- 2: SP: Left mid pole kidney region
- 3: SP: Left posterolateral mid pole kidney
- 4: SP: Anterior lower pole left kidney
- 5: SP: Lateral aspect lower pole left kidney

DIAGNOSIS:

- 1) KIDNEY, LEFT, LEFT UPPER POLE; PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, PAPILLARY TYPE, NUCLEAR GRADE III/IV, THE PATTERN OF GROWTH IS PAPILLARY. THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE. THE TUMOR GREATEST DIAMETER IS 4.0 CM. ALL SURGICAL MARGINS ARE FREE OF TUMOR. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE. THE ADRENAL GLAND IS NOT SUBMITTED/NOT IDENTIFIED.
- 2) KIDNEY, LEFT MID-POLE REGION; RESECTION:
- RENAL PARENCHYMA WITH NO EVIDENCE OF MALIGNANCY.
- 3) KIDNEY, LEFT POSTEROLATERAL MID-POLE; RESECTION:
- FIBROVASCULAR TISSUE WITH NO EVIDENCE OF MALIGNANCY.
- 4) KIDNEY, LEFT ANTERIOR LOWER POLE; RESECTION:
- FIBROADIPOSE TISSUE WITH NO EVIDENCE OF MALIGNANCY.
- 5) KIDNEY, LEFT, LATERAL ASPECT OF LOWER POLE; RESECTION:
- RENAL PARENCHYMA WITH NO EVIDENCE OF MALIGNANCY.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

[page 2 of 3]
1) The specimen is received fresh for frozen section, labeled as "Left upper pole left kidney tumor (stitch marks deep margin)". It consists of a partial nephrectomy specimen with attached fat. The portion of the kidney measures 6.5 x 5.5 x 3.5 cm. The surgical margin is marked with a stitch. The attached fat measures 13 x 6 x 1 cm. The fat overlying the bulging tumor and the surgical margins are inked. The specimen is serially sectioned revealing a fairly well circumscribed yellow friable tumor measuring 4 x 3.5 x 3.5 cm. The tumor does not appear to invade the renal capsule and it does not go into the perirenal fat. It is at least 0.9 cm away from the surgical margin of resection. The rest of the kidney parenchyma is tan-brown and unremarkable.

Summary of Sections:

TC - tumor to capsule

TS - tumor to surgical margin

K - kidney

F - perinephric fat

FSC - frozen section control

2) The specimen is received fresh for frozen section, labeled as "Left mid pole kidney region (r/o tumor)". It consists of two fragments of tan-brown soft tissue measuring 1.5 x 1 cm and 0.8 x 0.7 cm. Entirely submitted in one block.

Summary of sections:

FSC - frozen section control

3) The specimen is received fresh for frozen section, labeled as "Left posterior lateral mid pole kidney". It consists of fragments of red-tan soft tissue measuring 2 x 2 x 1 cm in aggregate. Entirely submitted in one block for frozen section.

Summary of sections:

FSC - frozen section control

4) The specimen is received fresh for frozen section, labeled as "Anterior lower pole left kidney". It consists of one fragment of tan soft tissue measuring 0.4 x 0.3 cm. Entirely submitted in one cassette.

Summary of sections:

FSC - frozen section control

5) The specimen is received fresh for frozen section, labeled as

[page 3 of 3]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file dff0a1b0-e538-4b0b-9416-544e9d5de0fb (TCGA-BQ-7046.BFB0EBFA-66D6-4A0C-892C-EFA5CFE53437.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).